Somatic mutation profile of tumor specimen MP2PRT-PAUBNM-TMP1-A (aliquot MP2PRT-PAUBNM-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAUBNM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,340 days).
Specimen MP2PRT-PAUBNM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a0be0ff-e4a1-4745-842f-3b92e1826b37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBNM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBNM-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7d2dbd5-ca89-49df-879e-4e3f0bae285a

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGA6L2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 161/399 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as rs1202766989; called by muse, mutect2, varscan2
- ADAM29 | c.737T>C p.F246S | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.143); called by muse, mutect2
- IGHV3-35 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 197/416 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- TCAF1 | c.2590_2605delinsCC p.D864Pfs*18 | Frame Shift Del (DEL) | VAF 111/795 reads (14%) | called by pindel, varscan2*
- IQCE | c.915G>A p.T305= | Silent (SNP) | VAF 57/495 reads (12%) | catalogued as rs749854999, COSV100383715; called by muse, mutect2, varscan2
- PCDH19 | c.3063T>C p.D1021= (on ENST00000373034 / NM_001184880.2; = p.D973= on NM_020766.3) | Silent (SNP) | VAF 259/265 reads (98%) | catalogued as rs900593958; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins GA | 3'Flank (INS) | VAF 60/88 reads (68%) | called by pindel, varscan2
